Gene-level copy-number profile of tumor specimen TCGA-CN-4727-01A from TCGA case TCGA-CN-4727, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Larynx, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: G2; Age at diagnosis: 56.8 years (20,748 days).
Specimen TCGA-CN-4727-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-HNSC.8bba5aba-62b5-45a4-98fa-6e47db10a5fa.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-CN-4727-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 808 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/acad1f79-eb40-4857-a47c-24000b9e7bc7

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 1; copy number 1: 2,409; copy number 2: 10,132; copy number 3: 27,650; copy number 4: 15,325; copy number 5: 2,522; copy number 6: 1,289; copy number 7: 117; copy number 8: 92; copy number 9: 116; copy number 10: 47; copy number 12: 40; copy number 13: 40; copy number 14: 5; copy number 25: 9; copy number 31: 21.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-CN-4727-01A-01D-1432-01): tumor purity 0.47, ploidy 3.26, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 1 gene in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr10:34,488,583–34,488,878, 1 gene: ELOBP4.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 487 genes in 10 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:143,091,362–143,768,352, 1 gene, copy number 9 (within-gene range 6–9): ARHGAP15.
- chr2:143,295,421–143,819,599, 6 genes, copy number 9: AC079793.1, AC092652.2, ARHGAP15-AS1, AC092652.1, AC079584.2, AC079584.1.
- chr2:171,317,405–175,463,180, 81 genes, copy number 7–12 (within-gene range 2–12) (broad region; genes not listed).
- chr3:187,668,912–192,119,864, 50 genes, copy number 7: SST, RTP2, AC072022.1, BCL6, AC072022.2, AC108681.1, AC068295.1, LINC01991, AC092941.1, AC092941.2, AC022498.1, LPP-AS2, LPP, FLJ42393, LPP-AS1, MIR28, TPRG1-AS1, TPRG1, AC009319.1, TPRG1-AS2, TP63, AC078809.1, MIR944, P3H2, MTAPP2, P3H2-AS1, RNU6-1109P, NMNAT1P3, CLDN1, CLDN16, TMEM207, IL1RAP, GCNT1P3, RN7SKP296, AC108747.1, LINC02013, CCT6P4, AC092952.1, GMNC, OSTN, OSTN-AS1, UTS2B, CCDC50, AC073365.1, PYDC2, Y_RNA, AC026320.2, AC026320.1, AC026320.3, RN7SKP222.
- chr3:192,238,037–192,283,097, 1 gene, copy number 7: FGF12-AS1.
- chr10:30,299,569–33,390,935, 71 genes, copy number 9–25 (broad region; genes not listed).
- chr11:69,294,151–70,436,584, 36 genes, copy number 10: MYEOV, IFITM9P, AP005233.2, AP005233.1, AP000439.2, AP000439.1, AP000439.3, LINC02747, LINC01488, CCND1, LTO1, FGF19, DNAJB6P5, FGF4, FGF3, AP007216.1, AP007216.2, AP003555.2, AP003555.1, LINC02753, LINC02584, RNU6-1175P, ANO1, AP000879.2, ANO1-AS1, FADD, AP000879.1, PPFIA1, H2AZP4, AP002336.2, MIR548K, AP002336.1, AP002336.3, AP000487.2, AP000487.1, CTTN.
- chr11:70,477,277–70,604,859, 2 genes, copy number 10: AP001271.1, AP001271.2.
- chr12:30,169,881–34,249,958, 104 genes, copy number 7–31 (broad region; genes not listed).
- chr18:580,380–7,232,047, 135 genes, copy number 7–12 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
